Somatic mutation profile of tumor specimen 0DWM1B from CCDI case PBCNEL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Commissure of lip; Age at diagnosis: 2.0 years (726 days).
Specimen 0DWM1B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) beb79f3d-056d-42cd-bb28-e77ea05fa21f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWLYO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bbf9f64-8277-46c3-a40c-41d9a5858641

The open-access MAF lists 86 somatic variants for this specimen: 53 protein-altering or splice-affecting, 20 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 20, Intron 6, 3'UTR 5, Nonsense Mutation 2, 5'Flank 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 258/542 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SDHB | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 156/695 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786203251, CM041829, CM092170, COSV100973407; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB8 | c.814C>A p.Q272K (on ENST00000297504 / NM_001282291.2; = p.Q255K on NM_007188.5) | Missense Mutation (SNP) | VAF 76/340 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99873837; called by muse, mutect2, varscan2
- AFF2 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 40/570 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV53978859; called by muse, mutect2
- AFG3L2 | c.854T>G p.M285R | Missense Mutation (SNP) | VAF 56/1059 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs1057524764; ClinVar: uncertain significance; called by muse, mutect2
- ASPA | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 34/874 reads (4%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.942); catalogued as CM023606, COSV53983337; called by muse, mutect2
- CSMD1 | c.7994C>A p.A2665E (on ENST00000520002; = p.A2664E on NM_033225.6) | Missense Mutation (SNP) | VAF 264/1298 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs1283613454; called by muse, mutect2, varscan2
- DNAH10 | c.4714G>A p.D1572N (on ENST00000409039; = p.D1511N on NM_207437.3) | Missense Mutation (SNP) | VAF 77/954 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs763643168, COSV68987679; called by muse, mutect2
- FANCM | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 38/1108 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1388696715, COSV57504627; called by muse, mutect2
- FOXI1 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 41/812 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60387997; called by muse, mutect2
- KCNJ1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 303/1044 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.342); catalogued as rs752507419, COSV60662207; called by muse, mutect2, varscan2
- NBEA | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 154/1424 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs267603808, COSV59766496, COSV59830102; called by muse, mutect2, varscan2
- NEUROD1 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 292/1859 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs747715154, COSV54549240, COSV54550542; called by muse, mutect2, varscan2
- NPHS1 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62287323, COSV62287505; called by muse, mutect2, varscan2
- OR4C3 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 32/922 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs1231760661, COSV60585829, COSV60590814; called by muse, mutect2
- OR4K17 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 30/1010 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV59648393; called by muse, mutect2
- PKLR | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 219/799 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.079); catalogued as rs763466930, COSV100712874; called by muse, mutect2, varscan2
- POMT2 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 60/1087 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1261175200; called by muse, mutect2
- PRTG | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 43/627 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.575); catalogued as rs1194416251, COSV66838058; called by muse, mutect2
- RP1 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 41/1331 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1454376137, COSV55112816; called by muse, mutect2
- TEX13C | c.2944C>T p.R982C | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.213); catalogued as rs950841810, COSV101084716; called by muse, mutect2
- USH2A | c.3263G>A p.S1088N | Missense Mutation (SNP) | VAF 116/1960 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.037); catalogued as COSV56449530; called by muse, mutect2
- UTRN | c.9518G>T p.W3173L | Missense Mutation (SNP) | VAF 559/2101 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as rs1305835770; called by muse, mutect2, varscan2
- ZSCAN30 | c.1475C>T p.T492I | Missense Mutation (SNP) | VAF 34/1162 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99734917; called by muse, mutect2
- ACTN2 | c.1787G>A p.S596N | Missense Mutation (SNP) | VAF 42/1125 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- ADAM29 | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 56/900 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- CCER2 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 22/695 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- DNHD1 | c.10858G>A p.E3620K | Missense Mutation (SNP) | VAF 60/1060 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.563); called by muse, mutect2
- EFEMP1 | c.966G>T p.Q322H | Missense Mutation (SNP) | VAF 286/1578 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by mutect2, varscan2
- EYS | c.3080C>T p.T1027I | Missense Mutation (SNP) | VAF 76/1766 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.134); called by muse, mutect2
- FAM47E-STBD1 | c.231G>T p.Q77H | Missense Mutation (SNP) | VAF 103/307 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAM98B | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 25/802 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by muse, mutect2
- FN1 | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 97/1613 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IQCA1 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 62/1791 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- LDHB | c.647A>G p.N216S | Missense Mutation (SNP) | VAF 56/1786 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); called by muse, mutect2
- LMO7 | c.2848C>T p.Q950* (on ENST00000357063; = p.Q631* on NM_005358.5) | Nonsense Mutation (SNP) | VAF 46/1094 reads (4%) | called by muse, mutect2
- LMTK2 | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 65/1170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NFIX | c.1355C>T p.S452F (on ENST00000592199 / NM_001365902.3; = p.S460F on NM_001271043.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/1000 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.247); called by muse, mutect2
- OR52L1 | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 36/607 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- PAQR3 | c.623G>A p.C208Y | Missense Mutation (SNP) | VAF 60/1540 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- PTCH1 | c.2174C>T p.P725L | Missense Mutation (SNP) | VAF 23/700 reads (3%) | SIFT tolerated (0.59); PolyPhen benign (0.01); called by muse, mutect2
- ROBO3 | c.2761G>C p.E921Q | Missense Mutation (SNP) | VAF 57/662 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.258); called by muse, mutect2
- SIGLEC11 | c.944G>T p.R315I | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by mutect2, varscan2
- SLC2A4 | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 24/404 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.05); called by muse, mutect2
- SLC39A7 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 26/790 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- TFRC | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 20/377 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); called by muse, mutect2
- TNFSF10 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 53/1082 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNS3 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 56/1016 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- TNXB | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 20/438 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, mutect2
- TTC6 | c.337G>T p.E113* (on ENST00000267368; = p.E1382* on NM_001310135.3) | Nonsense Mutation (SNP) | VAF 190/729 reads (26%) | called by muse, mutect2, varscan2
- UBLCP1 | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 147/742 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- WDFY4 | c.7000+1G>A p.X2334_splice | Splice Site (SNP) | VAF 24/598 reads (4%) | called by muse, mutect2
- ZDBF2 | c.2884G>C p.V962L | Missense Mutation (SNP) | VAF 658/2007 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ANKK1 | c.135G>A p.R45= | Silent (SNP) | VAF 50/646 reads (8%) | called by muse, mutect2
- ATP1A4 | c.3024T>C p.D1008= | Silent (SNP) | VAF 44/698 reads (6%) | catalogued as COSV63624346; called by muse, mutect2
- AVPR1A | c.843C>T p.S281= | Silent (SNP) | VAF 38/751 reads (5%) | catalogued as rs774865350; called by muse, mutect2
- BAZ2B | c.4395T>G p.S1465= | Silent (SNP) | VAF 79/2209 reads (4%) | called by muse, mutect2
- CACNA1C | c.1785C>T p.V595= | Silent (SNP) | VAF 72/542 reads (13%) | catalogued as rs755436625, COSV59781114; ClinVar: likely benign; called by muse, mutect2, varscan2
- CISH | c.498C>T p.S166= (on ENST00000348721 / NM_145071.4; = p.S183= on NM_013324.6) | Silent (SNP) | VAF 26/618 reads (4%) | called by muse, mutect2
- DNAH17 | c.11667G>A p.V3889= | Silent (SNP) | VAF 46/834 reads (6%) | called by muse, mutect2
- FTMT | c.159C>T p.A53= | Silent (SNP) | VAF 40/448 reads (9%) | called by muse, mutect2
- GPC1 | c.1167C>T p.V389= | Silent (SNP) | VAF 19/618 reads (3%) | called by muse, mutect2
- HNRNPCL2 | c.282C>T p.N94= | Silent (SNP) | VAF 291/1067 reads (27%) | catalogued as rs753248047; called by muse, mutect2, varscan2
- KCNV1 | c.672C>A p.I224= | Silent (SNP) | VAF 214/1044 reads (20%) | catalogued as COSV52088700; called by muse, mutect2, varscan2
- LRRIQ1 | c.4170T>C p.N1390= | Silent (SNP) | VAF 28/1109 reads (3%) | called by muse, mutect2
- MFGE8 | c.516C>T p.I172= | Silent (SNP) | VAF 48/742 reads (6%) | catalogued as COSV51557541; called by muse, mutect2
- MPDZ | c.591T>C p.D197= | Silent (SNP) | VAF 347/1256 reads (28%) | called by muse, mutect2, varscan2
- MYO1A | c.1911G>A p.R637= | Silent (SNP) | VAF 33/853 reads (4%) | catalogued as COSV100270866; called by muse, mutect2
- OR10AD1 | c.708G>A p.G236= | Silent (SNP) | VAF 58/780 reads (7%) | called by muse, mutect2
- PCDH11X | c.2898G>T p.L966= | Silent (SNP) | VAF 32/908 reads (4%) | called by muse, mutect2
- PCDHGA11 | c.2244G>A p.Q748= | Silent (SNP) | VAF 16/484 reads (3%) | called by muse, mutect2
- STARD9 | c.2427C>T p.V809= | Silent (SNP) | VAF 22/800 reads (3%) | called by muse, mutect2
- TBC1D30 | c.2451G>A p.A817= (on ENST00000542120; = p.A654= on NM_015279.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/300 reads (10%) | catalogued as rs922596048; called by muse, mutect2
- CCDC88B | c.3688-32C>T | Intron (SNP) | VAF 138/496 reads (28%) | catalogued as rs755032377; called by muse, mutect2
- CDRT1 | c.*36G>A | 3'UTR (SNP) | VAF 30/746 reads (4%) | called by muse, mutect2
- FUT6 | c.*93G>A | 3'UTR (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- GKN2 | c.*8A>T | 3'UTR (SNP) | VAF 30/974 reads (3%) | called by muse, mutect2
- KCNQ1 | c.*17G>A | 3'UTR (SNP) | VAF 15/528 reads (3%) | called by muse, mutect2
- LMAN1L | chr15:74812772 C>T | 5'Flank (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- LMAN1L | chr15:74812773 C>T | 5'Flank (SNP) | VAF 7/124 reads (6%) | called by muse, mutect2
- MGAM2 | c.1431+61G>A | Intron (SNP) | VAF 40/569 reads (7%) | catalogued as rs1433283540; called by muse, mutect2
- PES1 | c.1522-13C>T | Intron (SNP) | VAF 22/484 reads (5%) | called by muse, mutect2
- STK11 | c.862+15C>T | Intron (SNP) | VAF 62/346 reads (18%) | catalogued as rs1555738741; ClinVar: likely benign; called by muse, mutect2, varscan2
- TM4SF18 | c.*19C>T | 3'UTR (SNP) | VAF 38/1056 reads (4%) | called by muse, mutect2
- TSKS | c.1498-37C>T | Intron (SNP) | VAF 38/578 reads (7%) | called by muse, mutect2
- TTN | c.20453-31G>A | Intron (SNP) | VAF 66/1344 reads (5%) | called by muse, mutect2
